Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EJ, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EJ-01A (Primary Tumor).

Date of surgery :

Right eye enucleation

Macroscopy

The eyeball measures 25 by 25 mm with a segment of optic nerve of 10 mm. There is a posterior tumor close to the intraocular emergence of the optic nerve, pigmented , measuring 15 mm main line. Samples have been made for cryopreservation . The specimen has been then included entirely after fixation.

Microscopy

Choroidal melanoma with fusiform cells measuring 15 by 12 mm. The lesion , very posterior, is situated at the periphery, slightly distant from the intraocular emergence of the optic nerve which is free on its entire course(prelamina, optic foramen , post lamina part , cut end and meningeal sheaths)The proliferation superficially infiltrates the sclera but there is no extrasclerale extension. The lesion stays distant from the ciliary body , the iris , the anterior chamber which are free.

Conclusion

Choroidal melanoma with fusiform cells measuring 15 by 12 mm.

The lesion, very posterior, is situated at the periphery, slightly distant from the intraocular emergence of the optic nerve which is free on its entire course (prelamina, optic foramen , post lamina part , cut end and meningeal sheaths)

The proliferation superficially infiltrates the sclera but there is no extrasclerale extension.

The lesion stays distant from the ciliary body, the iris, the anterior chamber which is free.

ICD O-3

Melanoma, spindle cell NOS
8772/3

Site (R) Choroid
C69.3

9/10/14

IHPAA Discrepancy		☒

Source: NCI Genomic Data Commons file 7aeeccd1-f83a-480a-866a-826005c4b6ea (TCGA-V4-A9EJ.3677656F-1D21-4DE4-8DB5-F1681A72FA80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).